MMRF case MMRF_1546 — Multiple Myeloma CoMMpass Study (MMRF-COMMPASS)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Plasma Cell Tumors; Primary site: Hematopoietic and reticuloendothelial systems. Index date (day 0 for every day count below): first treatment.
https://portal.gdc.cancer.gov/cases/1531b2df-74e5-4201-8848-7bbbb8384245

Demographics
Sex at birth: male; Race: black or african american; Ethnicity: not hispanic or latino; Age at index: 67 years; Vital status: Alive.

Diagnoses (1)
1. Multiple myeloma: ICD-O-3 morphology code: 9732/3; Tissue or organ of origin: Bone marrow; Site of resection or biopsy: Bone marrow; Age at diagnosis: 67.8 years (24,752 days); ISS stage: II; Days to last known disease status: 1,268 days (3.5 years); Days to last follow up: 1,268 days (3.5 years).
   Treatment given: Therapeutic agents: Bortezomib + Dexamethasone + Lenalidomide; Regimen or line of therapy: First line of therapy; Days to treatment start: 1 day; Days to treatment end: 84 days.
   Treatment given: Therapeutic agents: Dexamethasone; Regimen or line of therapy: First line of therapy; Days to treatment start: 140 days; Days to treatment end: 596 days (1.6 years).
   Treatment given: Therapeutic agents: Lenalidomide; Regimen or line of therapy: First line of therapy; Days to treatment start: 140 days; Days to treatment end: 237 days.
   Treatment given: Therapeutic agents: Lenalidomide; Regimen or line of therapy: First line of therapy; Days to treatment start: 238 days; Days to treatment end: 386 days (1.1 years).
   Treatment given: Therapeutic agents: Lenalidomide; Regimen or line of therapy: First line of therapy; Days to treatment start: 386 days (1.1 years); Days to treatment end: 414 days (1.1 years).
   Treatment given: Therapeutic agents: Lenalidomide; Regimen or line of therapy: First line of therapy; Days to treatment start: 414 days (1.1 years); Days to treatment end: 534 days (1.5 years).
   Treatment given: Therapeutic agents: Lenalidomide; Regimen or line of therapy: First line of therapy; Days to treatment start: 534 days (1.5 years).
   Treatment given: Therapeutic agents: Dexamethasone; Regimen or line of therapy: First line of therapy; Days to treatment start: 596 days (1.6 years); Days to treatment end: 680 days (1.9 years).

Molecular and laboratory tests (laboratory values one line per visit day; values rounded to 3 significant figures where GDC's unit conversion carried more)
- Day -6: M Protein 5.38 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 8.88 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.69 mg/dL; Immunoglobulin G 63.6 g/L; Immunoglobulin A 0.53 g/L; Immunoglobulin M 0.17 g/L; Beta 2 Microglobulin 4.22 µg/mL; Lactate Dehydrogenase 3.03 µkat/L; Hemoglobin 6.39 mmol/L; Leukocytes 6.6 ×10⁹/L; Absolute Neutrophil 3.5 ×10⁹/L; Platelets 205 ×10⁹/L; Creatinine 133 µmol/L; Blood Urea Nitrogen 8.93 mmol/L; Calcium 2.33 mmol/L; Albumin 32 g/L; Total Protein 11.1 g/dL; Glucose 8.25 mmol/L; C-Reactive Protein 0.143 mg/dL.
- Day 57: M Protein 0.43 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 0.91 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.73 mg/dL; Immunoglobulin G 8.41 g/L; Immunoglobulin A 0.21 g/L; Immunoglobulin M 0.16 g/L; Beta 2 Microglobulin 2.08 µg/mL; Lactate Dehydrogenase 3.02 µkat/L; Hemoglobin 6.26 mmol/L; Leukocytes 4.2 ×10⁹/L; Absolute Neutrophil 2.44 ×10⁹/L; Platelets 250 ×10⁹/L; Creatinine 109 µmol/L; Blood Urea Nitrogen 5 mmol/L; Calcium 2.35 mmol/L; Albumin 36 g/L; Total Protein 6.8 g/dL; Glucose 11.7 mmol/L.
- Day 176: M Protein 0.26 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 1.47 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.64 mg/dL; Immunoglobulin G 8.45 g/L; Immunoglobulin A 0.53 g/L; Immunoglobulin M 0.18 g/L; Beta 2 Microglobulin 2.39 µg/mL; Hemoglobin 7.25 mmol/L; Leukocytes 5.4 ×10⁹/L; Absolute Neutrophil 4.3 ×10⁹/L; Platelets 211 ×10⁹/L; Creatinine 77.8 µmol/L; Blood Urea Nitrogen 4.64 mmol/L; Calcium 2.35 mmol/L; Albumin 36 g/L; Total Protein 6.6 g/dL; Glucose 7.7 mmol/L.
- Day 261: M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 2.09 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.911 mg/dL; Immunoglobulin G 6.96 g/L; Immunoglobulin A 0.92 g/L; Immunoglobulin M 0.18 g/L; Beta 2 Microglobulin 1.66 µg/mL.
- Day 357: M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 2.16 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.901 mg/dL; Beta 2 Microglobulin 1.81 µg/mL; Hemoglobin 6.51 mmol/L; Leukocytes 3.2 ×10⁹/L; Absolute Neutrophil 1.43 ×10⁹/L; Platelets 179 ×10⁹/L; Creatinine 81.3 µmol/L; Blood Urea Nitrogen 4.28 mmol/L; Calcium 2.3 mmol/L; Albumin 34 g/L; Total Protein 6.1 g/dL; Glucose 9.19 mmol/L.
- Day 463: M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 2.39 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.16 mg/dL; Beta 2 Microglobulin 1.86 µg/mL; Creatinine 73.4 µmol/L; Blood Urea Nitrogen 3.57 mmol/L; Calcium 2.25 mmol/L; Albumin 36 g/L; Total Protein 5.7 g/dL; Glucose 10.5 mmol/L.
- Day 534: M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 2.77 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.23 mg/dL; Immunoglobulin G 8.26 g/L; Immunoglobulin A 1.97 g/L; Immunoglobulin M 0.28 g/L; Beta 2 Microglobulin 1.73 µg/mL; Lactate Dehydrogenase 2.17 µkat/L; Hemoglobin 7.63 mmol/L; Leukocytes 3.5 ×10⁹/L; Absolute Neutrophil 1.73 ×10⁹/L; Platelets 158 ×10⁹/L; Creatinine 70.7 µmol/L; Blood Urea Nitrogen 3.21 mmol/L; Calcium 2.33 mmol/L; Albumin 35 g/L; Total Protein 6.4 g/dL; Glucose 7.26 mmol/L.
- Day 652: M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 2.57 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.42 mg/dL; Immunoglobulin G 8.38 g/L; Immunoglobulin A 1.96 g/L; Immunoglobulin M 0.23 g/L; Beta 2 Microglobulin 2.04 µg/mL; Hemoglobin 7.75 mmol/L; Leukocytes 3.7 ×10⁹/L; Absolute Neutrophil 1.67 ×10⁹/L; Platelets 154 ×10⁹/L; Creatinine 91.9 µmol/L; Blood Urea Nitrogen 5 mmol/L; Calcium 2.3 mmol/L; Albumin 32.1 g/L; Total Protein 5.8 g/dL; Glucose 5.34 mmol/L.
- Day 708 (ECOG 1): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 2.88 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.1 mg/dL; Immunoglobulin G 8.76 g/L; Immunoglobulin A 2.14 g/L; Immunoglobulin M 0.25 g/L; Beta 2 Microglobulin 2.62 µg/mL; Lactate Dehydrogenase 2.5 µkat/L; Hemoglobin 8.06 mmol/L; Leukocytes 4 ×10⁹/L; Absolute Neutrophil 2 ×10⁹/L; Platelets 180 ×10⁹/L; Creatinine 97.2 µmol/L; Blood Urea Nitrogen 4.28 mmol/L; Calcium 2.25 mmol/L; Albumin 37 g/L; Total Protein 6.8 g/dL; Glucose 8.47 mmol/L.
- Day 792 (ECOG 2): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 5.08 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.41 mg/dL; Immunoglobulin G 11.4 g/L; Immunoglobulin A 2.75 g/L; Immunoglobulin M 0.33 g/L; Beta 2 Microglobulin 1.86 µg/mL; Lactate Dehydrogenase 3 µkat/L; Hemoglobin 7.44 mmol/L; Leukocytes 4.1 ×10⁹/L; Absolute Neutrophil 1.92 ×10⁹/L; Platelets 194 ×10⁹/L; Creatinine 103 µmol/L; Blood Urea Nitrogen 4.64 mmol/L; Calcium 2.2 mmol/L; Albumin 35 g/L; Total Protein 6.6 g/dL; Glucose 6 mmol/L.
- Day 918: M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 4.89 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.72 mg/dL; Immunoglobulin G 12.6 g/L; Immunoglobulin A 2.84 g/L; Immunoglobulin M 0.29 g/L; Beta 2 Microglobulin 2.01 µg/mL; Lactate Dehydrogenase 2.92 µkat/L; Hemoglobin 7.44 mmol/L; Leukocytes 5.6 ×10⁹/L; Absolute Neutrophil 3.78 ×10⁹/L; Platelets 226 ×10⁹/L; Creatinine 116 µmol/L; Blood Urea Nitrogen 4.64 mmol/L; Calcium 2.18 mmol/L; Albumin 35 g/L; Total Protein 7.6 g/dL; Glucose 5.34 mmol/L.
- Day 967: Hemoglobin 7.25 mmol/L; Leukocytes 7.3 ×10⁹/L; Platelets 217 ×10⁹/L.
- Day 1,086: M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 8.33 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 2.72 mg/dL; Immunoglobulin G 13.8 g/L; Immunoglobulin A 4 g/L; Immunoglobulin M 0.31 g/L; Beta 2 Microglobulin 2.06 µg/mL; Lactate Dehydrogenase 2.47 µkat/L; Hemoglobin 7.01 mmol/L; Leukocytes 4.4 ×10⁹/L; Absolute Neutrophil 2.68 ×10⁹/L; Platelets 210 ×10⁹/L; Creatinine 131 µmol/L; Blood Urea Nitrogen 3.57 mmol/L; Calcium 2.25 mmol/L; Albumin 37 g/L; Total Protein 7.2 g/dL; Glucose 10.4 mmol/L.
- Day 1,199: M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 9.08 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 2.7 mg/dL; Immunoglobulin G 14.4 g/L; Immunoglobulin A 5.28 g/L; Immunoglobulin M 0.3 g/L; Beta 2 Microglobulin 2.41 µg/mL; Hemoglobin 7.5 mmol/L; Leukocytes 5.1 ×10⁹/L; Absolute Neutrophil 3.03 ×10⁹/L; Platelets 250 ×10⁹/L; Creatinine 115 µmol/L; Blood Urea Nitrogen 3.93 mmol/L; Calcium 2.18 mmol/L; Albumin 34 g/L; Total Protein 7.5 g/dL; Glucose 11.2 mmol/L.
- Day 1,268 (ECOG 1): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 7.99 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 2.82 mg/dL; Immunoglobulin G 5.36 g/L; Immunoglobulin A 15.9 g/L; Immunoglobulin M 0.28 g/L; Beta 2 Microglobulin 2.2 µg/mL; Lactate Dehydrogenase 2.3 µkat/L; Hemoglobin 6.88 mmol/L; Leukocytes 4.4 ×10⁹/L; Absolute Neutrophil 2.52 ×10⁹/L; Platelets 214 ×10⁹/L; Creatinine 111 µmol/L; Blood Urea Nitrogen 5 mmol/L; Calcium 2.23 mmol/L; Albumin 34 g/L; Total Protein 7.2 g/dL; Glucose 13.5 mmol/L.

Other clinical attributes
- Day -6: Weight: 100 kg; Height: 171 cm.

Family history
- Relative with cancer history: no.

Biospecimens (2 samples)
- Sample MMRF_1546_1_BM_CD138pos: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS; Days to sample procurement: -6 days.
- Sample MMRF_1546_1_PB_Whole: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS; Days to sample procurement: -6 days.
